Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A50T, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A50T-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT:

ACCT #:

LOC:

REG DR:

AGE/SX:

ROOM:

DOB:

BED:

STATUS:

SPEC #:

RECD:

STATUS:

COLL:

TIME IN FORMALIN:

CLINICAL INFORMATION:

Pre-Op Diagnosis: Sigmoid colon neoplasm

Remarks:

- Specimen(s):
- A. Liver biopsy left lobe
- B. Splenic flexure colon lesion
- C. Left lobe liver biopsy
- D. Pelvic peritoneal nodule

MICROSCOPIC DIAGNOSIS

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: colon, splenic flexure c18.5
lw 11/7/12

- A. LEFT LOBE LIVER (BIOPSY):
- GRANULOMATOUS INFLAMMATION
- NEGATIVE FOR ORGANISMS ON ACID FAST AND FUNGAL STAINS
- B. COLON AT SPLENIC FLEXURE (LAPAROSCOPIC SEGMENTAL RESECTION):
- MODERATELY DIFFERENTIATED ADENOCARCINOMA, INVADING THROUGH THE BOWEL WALL
- NO METASTASIS IN 10 REGIONAL LYMPH NODES
- ALL MARGINS UNINVOLVED
- SEE COMMENT FOR SYNOPTIC REPORT
- C. LEFT LOBE LIVER (BIOPSY):
- GRANULOMATOUS INFLAMMATION
- NEGATIVE FOR ORGANISMS ON ACID FAST AND FUNGAL STAINS
- D. PELVIC PERITONEAL NODULE (BIOPSY):
- FAT NECROSIS WITH FIBROSIS AND CALCIFICATION

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - CAP APPROVED

Specimen:	Transverse colon, descending colon
Procedure:	Laparoscopic resection
	Specimen Length: 12 cm
Tumor Site:	Splenic flexure
Tumor Size:	6 cm in greatest dimension
Macroscopic Tumor Perforation:	Not identified
Histologic Type:	Adenocarcinoma
Histologic Grade:	Low-grade
Microscopic Tumor Extension:	Tumor invades through the muscularis propria into the

** CONTINUED ON NEXT PAGE **

[page 2 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

SPEC #: [REDACTED]

PATIENT: [REDACTED]

(Continued)

COMMENT(S)

(Continued)

Margins:

subserosal adipose tissue
Distance of invasive carcinoma from closest margin: 2
cm; mucosal margin opposite tattooed margin
Proximal: Uninvolved by invasive carcinoma
Distal: Uninvolved by invasive carcinoma
Circumferential: Uninvolved by invasive carcinoma

Treatment Effect:

No prior treatment

Lymph-Vascular Invasion:

Not identified

Perineural Invasion:

Not identified

Tumor Deposits:

Present

Pathologic Staging:

Primary Tumor: pT3

Regional Lymph Nodes: pN0

Number examined: 10

Number involved: 0

Distant Metastasis: Not applicable

GROSS DESCRIPTION:

A. Received fresh for frozen section labeled with the patient's name and "liver biopsy" is a 1 x 0.4 x 0.3 cm linear biopsy of tan tissue totally submitted in block A for frozen section evaluation.

B. Received fresh labeled with the patient's name and "splenic flexure colon lesion" with tissue bank coordinator in attendance is a 12 cm segmental resection of large bowel which measures 4 cm in diameter. requests gross evaluation for margins. Both the surgical margins are stapled and not clinically designated. Tattoo pigment is noted which abuts one staple line. The adipose tissue is wrapped around the serosa in the mid portion. Blue ink is applied to this area. The tattoo stapled margin measures 5 cm in length and opposite margin measures 3.5 cm in length. The mesenteric margin measures 3 cm. Blue ink is applied to this margin. In trying to separate the mesentery from the bowel, it is found to be adherent to the bowel surface. There is some fatty tissue present on the opposite side which may be inclusive of some omental type tissue. The margins are removed and the lumen probed revealing an obstructing mass present. The tumor measures 6 cm in length, it involves the entire circumference of the bowel wall. It lies 2.5 cm from the tattooed margin and 2 cm from the opposite margin. A portion of the edge of the tumor and non-neoplastic mucosa is provided to the tissue bank coordinator. The specimen is pinned out onto a corkboard for several hours of formalin fixation. The partial fixed specimen is serially sectioned revealing that the tumor extends deep into the muscle wall, possibly extending through the muscle wall. A subjacent lymph node is identified measuring 1 cm. The pericolic/mesenteric adipose tissue was placed in a 50/50 solution of lymph node revealing solution and formalin. On cross section, several lymph nodes are identified which range from 0.4 to 1 cm in greatest dimension each. No omental nodules are identified.

Cassette Summary:

B1,2 - tattoo pigment

B3-8 - representative sections of tumor with blocks 3 and 4 demonstrating adjacent

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE:

RUN TIME:

RUN USER:

Specimen Inquiry

PAGE 3

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

- lymph node
- B9 - omental tissue
- B11-13- two lymph nodes each bisected and totally submitted, one inked
- B14 - largest lymph node sectioned and totally submitted

C. In formalin labeled with the patient's name and "left lobe liver biopsy" is a 0.7 x 1 x 0.3 cm biopsy of liver tissue. There is a 0.5 x 0.4 cm pale area on the surface. The biopsy is trisected and entirely submitted in block C.

D. In formalin labeled with the patient's name and "pelvic peritoneal nodule" is a 1 x 1 x 0.5 cm triangular shaped portion of gray fatty tissue. There is a 3 mm whitish nodule on the surface. The specimen is bisected revealing this to be a partially calcified hemorrhagic nodule possibly representing fat necrosis. The specimen is entirely submitted in block D.

MICROSCOPIC DESCRIPTION:

A&C. These biopsies of the left lobe of the liver show focal granulomatous inflammation with fibrosis. The granulomas are mostly noncaseating, composed of epithelioid histiocytes, multinucleated giant cells and a sprinkling of small lymphocytes. These granulomas are set in a fibrous stroma. A few of the granulomas have scant central necrosis but most are noncaseating. AFB and GMS stains are obtained on both biopsies. No organisms are seen.

D. This is a piece of adipose tissue containing a sclerotic, partially calcified nodule compatible with fat necrosis. There is no evidence of metastatic carcinoma.

B. Sections of the obstructing tumor demonstrate a moderately differentiated adenocarcinoma which invades through the bowel wall, not quite reaching the subjacent mesenteric lymph node. Discontinuous invasion is noted. No metastasis are identified in 10 regional lymph nodes.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

A. LIVER BIOPSY:

- NECROTIZING GRANULOMATOUS INFLAMMATION
- NEGATIVE FOR CARCINOMA
- RESULTS GIVEN TO IN OPERATING ROOM AT

B. SPLENIC FLEXURE MASS:

- GROSS OBSTRUCTING CARCINOMA WITH MARGINS AS FOLLOWS: TATTOO STAPLE LINE 2.5 CM AND OPPOSITE STAPLE LINE 2 CM
- FINDINGS GIVEN TO IN THE OPERATING ROOM AT

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 4

SPEC #: [REDACTED]

PATIENT: [REDACTED]

(Continued)

PHOTO DOCUMENTATION

Image

Picture Copy Error

Signed ____ (signature on file) ____ [REDACTED]

** END OF REPORT **

IJIPAA Discrepancy		X

11/9/12

Source: NCI Genomic Data Commons file 7586e688-7681-4ab0-a310-d409e800ab21 (TCGA-NH-A50T.79B9D161-8397-455C-AC36-7DED2D211C95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).